Somatic mutation profile of tumor specimen TCGA-DU-6407-01A (aliquot TCGA-DU-6407-01A-13D-1705-08) from TCGA case TCGA-DU-6407, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 35.6 years (13,021 days).
Specimen TCGA-DU-6407-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 884bec80-b4b8-4949-a05a-9bdc22c12233.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-6407-10A (Blood Derived Normal), aliquot TCGA-DU-6407-10A-01D-1705-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c7c4ee9-d46f-4a8f-9ecd-d9165ef069e9

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, 5'UTR 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 25/65 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.325T>G p.F109V | Missense Mutation (SNP) | VAF 57/64 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057523496, COSV52819746, COSV53616876; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CAMK1D | c.394G>A p.V132M | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1287192477, COSV66610827; called by muse, mutect2, varscan2
- CBX5 | c.479G>A p.C160Y | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as COSV52936679; called by muse, mutect2, varscan2
- CFAP47 | c.4565C>A p.S1522Y | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV57972708; called by muse, mutect2, varscan2
- CYP26B1 | c.1309G>A p.G437S | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1228321015, COSV50011655; called by muse, mutect2, varscan2
- FPGT | c.1207C>A p.P403T | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV100907074, COSV100907141; called by muse, mutect2, varscan2
- HPS1 | c.1200T>G p.D400E | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.185); catalogued as COSV57267640; called by muse, mutect2, varscan2
- IGF2R | c.5768C>T p.A1923V | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs368781979; called by muse, mutect2, varscan2
- LGI4 | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.355); catalogued as COSV59533425; called by muse, mutect2
- MIPEP | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV66300433; called by muse, mutect2, varscan2
- PDK1 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.181); catalogued as COSV56375257; called by muse, mutect2, varscan2
- SCN1A | c.3502G>A p.V1168I (on ENST00000303395 / NM_001202435.3; = p.V1157I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.245); catalogued as rs146374754; ClinVar: uncertain significance; called by muse, mutect2
- USP25 | c.2773T>C p.S925P | Missense Mutation (SNP) | VAF 34/211 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as rs752333568, COSV53483855; called by muse, mutect2, varscan2
- ZDHHC7 | c.830G>A p.G277E | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.558); catalogued as rs1255467521, COSV58212400; called by muse, mutect2, varscan2
- ACACA | c.605A>G p.N202S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ATRX | c.1405_1408del p.V469Ifs*44 | Frame Shift Del (DEL) | VAF 120/369 reads (33%) | called by mutect2, pindel, varscan2
- GATA3 | c.411G>A p.S137= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as rs745734873, COSV60518006; called by muse, mutect2, varscan2
- HELZ | c.4044T>C p.A1348= | Silent (SNP) | VAF 47/91 reads (52%) | catalogued as COSV62378124; called by muse, mutect2, varscan2
- HNF1B | c.1539C>T p.Y513= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs780554506; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSPG2 | c.7842C>T p.I2614= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs1309975355, COSV65971182; called by muse, mutect2
- LMCD1 | c.573C>T p.S191= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as rs768375620, COSV50087416; called by muse, mutect2, varscan2
- MYO3A | c.1245T>C p.Y415= | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as COSV56329175; called by muse, mutect2
- RETREG1 | c.1170G>A p.T390= (on ENST00000306320 / NM_001034850.2; = p.T249= on NM_019000.4) | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as rs369353830; called by muse, mutect2, varscan2
- HOMER3 | c.*153C>T | 3'UTR (SNP) | VAF 17/43 reads (40%) | catalogued as rs1020417998, COSV99651027; called by muse, mutect2, varscan2
- MRPL47 | c.-1C>T | 5'UTR (SNP) | VAF 47/106 reads (44%) | catalogued as rs1445679552, COSV99372522; called by muse, mutect2, varscan2
